Somatic mutation profile of tumor specimen 0DXLTQ from CCDI case PBCRKL, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Pilocytic astrocytoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 0.8 years (308 days).
Specimen 0DXLTQ: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1414fbb2-f5b2-44ca-8b3b-fad3d44ebb33.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DXLT2 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/dd8d4df7-3f98-4ad2-ba31-4d20cff6ed63

The open-access MAF lists 3 somatic variants for this specimen: 1 protein-altering or splice-affecting, 2 silent.
By variant classification: Silent 2, Missense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- REG1A | c.161G>A p.R54H | Missense Mutation (SNP) | VAF 54/497 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.001); catalogued as rs768985544, COSV52072250; called by muse, mutect2, varscan2
- CHST4 | c.135G>A p.V45= | Silent (SNP) | VAF 23/591 reads (4%) | called by muse, mutect2
- SLC5A10 | c.816C>A p.I272= | Silent (SNP) | VAF 48/239 reads (20%) | called by muse, mutect2, varscan2
